Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7404, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7404-01A (Primary Tumor).

Accession Number: [REDACTED]

Final Report

DIAGNOSIS:

1,2) TONSIL, LEFT TONSILLECTOMY: MODERATELY-DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA.

Electronically signed by: [REDACTED].

CLINICAL DATA

Clinical Features/Dx: unspecified
Operator: [REDACTED]
Operation: unspecified
Operative Findings: unspecified
Operative Diagnosis: unspecified
Tissue Submitted: 1) left tonsil, 2) left tonsil

GROSS DESCRIPTION:

1) SOURCE: Tonsil, Left

Received fresh labeled, "left tonsil," is a 1.2 x 1.0 x 0.3 cm aggregate of pink-tan tissue. The specimen is submitted in total.
Summary of sections: 1A, m/1.

2) SOURCE: Tonsil, Left

Received fresh labeled, "left tonsil," is a 1.0 x 1.0 x 0.3 cm aggregate of pink-tan tissue. A portion of this tissue is submitted for research as per request. The remaining tissue is filtered and submitted in total.
Summary of sections: 2A, m/1.

SNOMED: T-C5100,M-80703,

Source: NCI Genomic Data Commons file 46a11a5e-d4c4-4d0e-b3d2-b48db74e5ed5 (TCGA-CR-7404.AF669AB2-28C3-41EC-916E-C858FFEF8CCC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).